Gene-level copy-number profile of tumor specimen HCM-CSHL-0241-C18-01A from HCMI case HCM-CSHL-0241-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-CSHL-0241-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31ca303b-400b-415b-a6d6-be1d3e29a7e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0241-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/464decbd-a6c7-488d-93a2-a54b68554d2d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 6,203; copy number 2: 44,364; copy number 3: 6,663; copy number 5: 981; copy number 6: 5; copy number 7: 175.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–2): RNU6-457P.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr16:32,635,673–32,636,045, 1 gene: AC133569.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,161 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:139,618,136–151,991,925, 175 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr16:32,649,193–32,678,831, 5 genes, copy number 6: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr20:6,074,845–11,029,455, 59 genes, copy number 5: FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2, AL096799.1, LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1.
- chr20:19,757,606–22,746,991, 57 genes, copy number 5 (within-gene range 3–5): RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3.
- chr20:24,063,255–24,666,616, 7 genes, copy number 5: LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1.
- chr20:31,257,664–64,327,972, 858 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
